Somatic mutation profile of tumor specimen 0DOG3J from CCDI case PBCCJY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.3 years (481 days).
Specimen 0DOG3J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f71c1ca7-83a4-4e47-a408-f09e5d58a4b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOG2Z (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a968e1fe-de2b-444f-a085-3d8188a3f86f

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH11 | c.1390C>T p.H464Y | Missense Mutation (SNP) | VAF 114/289 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.312); catalogued as rs772881140, COSV51750074; called by muse, mutect2, varscan2
- USP14 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 12/386 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs868742729, COSV99864243; called by muse, mutect2
- ZFPM2 | c.2266G>T p.V756F | Missense Mutation (SNP) | VAF 19/520 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.146); called by muse, mutect2
